Gene-level copy-number profile of tumor specimen TCGA-61-2611-02A from TCGA case TCGA-61-2611, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 40.5 years (14,782 days).
Specimen TCGA-61-2611-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.7e9a894d-11d2-49b6-af84-e8d9723942e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2611-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7cb7ebec-fed2-4514-b5ac-e0792462d77f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,630; copy number 2: 14,108; copy number 3: 18,601; copy number 4: 15,654; copy number 5: 7,550; copy number 6: 706; copy number 7: 227; copy number 8: 4; copy number 9: 224; copy number 11: 104.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-2611-02A-01D-1134-01): tumor purity 0.29, ploidy 2.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 559 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:118,189,455–118,906,155, 4 genes, copy number 8 (within-gene range 5–8): SAMD12, AC023590.1, SAMD12-AS1, RPS26P35.
- chr12:38,544,177–52,229,588, 343 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr18:3,496,032–4,455,307, 1 gene, copy number 7 (within-gene range 3–7): DLGAP1.
- chr18:3,962,353–6,415,237, 31 genes, copy number 7 (within-gene range 4–7): DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1, PPIAP14, LINC01892, BOD1P2, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1, AP005671.1, EPB41L3, AP005059.2, AP005059.1, MIR3976HG, MIR3976, TMEM200C, AP001021.1, AP001021.3, L3MBTL4, AP001021.2, RNU5F-3P, L3MBTL4-AS1.
- chr20:4,422,186–5,864,395, 37 genes, copy number 7: AL139350.1, AL121781.1, AL121916.1, RPS4XP2, PRNP, PRND, PRNT, IDI1P3, AL133396.1, RASSF2, SLC23A2, AL389886.1, AL121890.1, AL121890.3, AL121890.2, AL121890.5, AL121890.4, TMEM230, RNA5SP474, Y_RNA, PCNA, AL121924.1, CDS2, UBE2D3P1, PROKR2, AL121757.2, RNA5-8SP7, AL121757.3, LINC00658, AL121757.1, LINC00654, LINC01729, RPS18P1, AL109935.1, GPCPD1, EIF4EP1, SHLD1.
- chr20:61,252,261–61,940,617, 1 gene, copy number 7 (within-gene range 5–7): CDH4.
- chr20:61,369,879–64,313,132, 142 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,630. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
